CCDI case PBCNNH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas.
https://portal.gdc.cancer.gov/cases/8166d2a8-5a81-4832-8782-4eb3e8635bc0

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Sympathetic paraganglioma: ICD-O-3 morphology code: 8681/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 22.9 years (8,373 days).

Biospecimens (3 samples)
- Sample 0DWRMA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWRMU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWRMY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
